Surgical pathology report (de-identified scan), TCGA case TCGA-SU-A7E7, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Global Bioclinical-Moldova, specimen TCGA-SU-A7E7-01A (Primary Tumor).

Final Pathology Template

Final Pathology Report Information (Surgical Tissue Case)

- 1.1 Tissue Specimen ID Code: _____
- 1.2 Date of Excision: _____ Tumor Location (anatomic site): **Prostate**
ICD-O-3
- 1.3 Tumor Size: **0,5 x 1,0 x 1,3 (cm)** *Adenocarcinoma, acinar 8/40/13*
- 1.4 Lymph Node Status: *Site: Prostate NOS 061.9*
1.4.1 Number Nodes Examined: **9**
1.4.2 Number Nodes Positive: **0**
1.4.3 Lymph Node Locations (Involved Nodes): **obturator, iliac** *9/24/13*
- 1.5 Metastasis:
1.5.1 Metastasis Present: ☐ Yes ☒ No ☐ Unknown
1.5.2 Number of Mets: _____
1.5.3 Site(s) Of Metastasis: _____
- 1.6 ICD-9 Code for Specimen Diagnosis: **C 61.9**
- 1.7 Final Pathology Details:
(Please supply de-identified copy of original language final pathology report in addition to information below)
- 1.7.1 Macroscopic Description: **Prostate measuring 5,0 x 4,0 x 3,0 cm with macroscopically intact seminal vesicles, on section with nodular tumor of 0,5x1,0x1,3cm in dimension. Separately 9 lymph nodes of pink color.**
- 1.7.2 Microscopic Description: **Poorly differentiated prostate adenocarcinoma, acinar type. Gleason score (5+3=8). Background -adenomatous hyperplasia of the prostate. Surgical margins is intact. Lymph nodes status - negative (obturator and iliac).**
- 1.7.3 Comment (if applicable): _____
- 1.7.4 Clinical Diagnosis: **Cancer of prostate**
- 1.7.5 Stage: **T2 N0 M0, II B**

PROPRIETARY AND CONFIDENTIAL

Source: NCI Genomic Data Commons file 7ef32b62-4188-401f-bedf-86dbf04baa4b (TCGA-SU-A7E7.120AA6E7-735D-442E-99AA-4EFE93C365F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).